Somatic mutation profile of tumor specimen TCGA-B0-4827-01A (aliquot TCGA-B0-4827-01A-02D-1421-08) from TCGA case TCGA-B0-4827, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 77.9 years (28,467 days).
Specimen TCGA-B0-4827-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f4d25de-ce67-4b1f-89c8-82ea781b7f94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4827-11A (Solid Tissue Normal), aliquot TCGA-B0-4827-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/957d2944-02ef-4d8f-b365-2340f96682b5

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 17, Frame Shift Del 7, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, 5'Flank 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.5930C>A p.T1977K | Missense Mutation (SNP) | VAF 88/253 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs587777893, COSV63868784, COSV63869673, COSV63869920; ClinVar: not provided; called by muse, mutect2, varscan2
- PRUNE1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752599948, COSV54956721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1559429613, CM941380, COSV56544074, COSV56552085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1478T>A p.F493Y | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs1318814475, COSV52220476; called by muse, mutect2, varscan2
- ABCD4 | c.1216G>C p.D406H | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53991799; called by muse, mutect2, varscan2
- ADGRG4 | c.5713A>T p.N1905Y | Missense Mutation (SNP) | VAF 69/417 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV54953365; called by muse, mutect2, varscan2
- AKAP9 | c.4646C>G p.S1549* | Nonsense Mutation (SNP) | VAF 64/281 reads (23%) | catalogued as COSV62343114; called by muse, mutect2, varscan2
- AKT2 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV60908118; called by muse, mutect2
- ALG5 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53504946; called by muse, varscan2
- ATP12A | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54514645; called by muse, mutect2, varscan2
- BAP1 | c.848del p.E283Gfs*52 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | catalogued as COSV56232863; called by mutect2, pindel, varscan2
- CARD11 | c.3417C>G p.I1139M | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67798267; called by muse, mutect2, varscan2
- CCDC51 | c.967C>G p.Q323E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV56488557; called by muse, mutect2, varscan2
- CPED1 | c.2723G>A p.S908N | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs767990682, COSV100121348, COSV60000020; called by muse, varscan2
- CTSV | c.632G>C p.C211S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52344612; called by muse, mutect2
- DCUN1D3 | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60952919; called by muse, mutect2, varscan2
- EPHB6 | c.2687T>G p.L896W | Missense Mutation (SNP) | VAF 95/413 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63891241; called by muse, mutect2, varscan2
- FANCG | c.481T>A p.L161M | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.387); catalogued as COSV62720136; called by muse, mutect2, varscan2
- FCHO2 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV55107460; called by muse, mutect2, varscan2
- FNTB | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs750508990, COSV55760864; called by muse, mutect2, varscan2
- KCNB2 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73049669; called by muse, mutect2, varscan2
- KIAA1549L | c.2066C>G p.T689R (on ENST00000321505; = p.T986R on NM_012194.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV55771877; called by muse, mutect2
- LPCAT2 | c.698A>T p.K233I | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50894861; called by muse, mutect2, varscan2
- MAGEC1 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 85/460 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.641); catalogued as rs1480954625, COSV53570940, COSV53575540; called by muse, mutect2, varscan2
- MDN1 | c.12392T>G p.F4131C | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65520056; called by muse, mutect2, varscan2
- MISP | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs764841731, COSV53119511; called by muse, mutect2, varscan2
- MUC16 | c.20701C>A p.Q6901K | Missense Mutation (SNP) | VAF 83/452 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.181); catalogued as rs1022497487, COSV67458226; called by muse, mutect2, varscan2
- MYH3 | c.5125G>T p.D1709Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56861150, COSV56863378; called by muse, mutect2, varscan2
- NDST4 | c.1939T>G p.W647G | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52115105; called by muse, mutect2, varscan2
- NFATC3 | c.1852A>G p.M618V | Missense Mutation (SNP) | VAF 69/461 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV60472674; called by muse, mutect2, varscan2
- NOL11 | c.1854G>C p.K618N | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV53522937; called by muse, mutect2, varscan2
- NOS1 | c.3113T>A p.L1038Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57610100; called by muse, mutect2, varscan2
- NT5DC3 | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67321172, COSV67321557; called by muse, mutect2, varscan2
- OR51T1 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV59024777; called by muse, mutect2, varscan2
- PARP6 | c.1419-1G>A p.X473_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | catalogued as COSV53002678; called by muse, mutect2
- PHF14 | c.2016T>G p.N672K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV68854905; called by muse, mutect2, varscan2
- PPIP5K1 | c.934T>C p.F312L | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV58477834; called by muse, mutect2, varscan2
- RANBP10 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58156063; called by muse, mutect2, varscan2
- RANBP6 | c.2171A>C p.H724P | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52388965; called by muse, mutect2, varscan2
- RGS9 | c.114C>A p.N38K | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as COSV52224402; called by muse, mutect2, varscan2
- RNF10 | c.1685G>T p.R562I | Missense Mutation (SNP) | VAF 60/355 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58044456; called by muse, mutect2, varscan2
- RNF38 | c.171T>A p.D57E | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.952); catalogued as COSV52393952; called by muse, mutect2, varscan2
- ROS1 | c.4049C>A p.P1350Q | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV63853659; called by muse, mutect2, varscan2
- SCN2A | c.2079T>G p.D693E | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV51837655; called by muse, mutect2, varscan2
- SEPTIN4 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57895675; called by muse, mutect2
- SHLD1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57436128; called by muse, mutect2, varscan2
- SNX25 | c.598A>T p.R200W | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53013140; called by muse, mutect2, varscan2
- SPEN | c.6706C>T p.P2236S | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1379898454, COSV65360312; called by muse, mutect2, varscan2
- SREK1 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52332460; called by muse, mutect2, varscan2
- SZT2 | c.7210G>A p.G2404R (on ENST00000634258 / NM_001365999.1; = p.G2347R on NM_015284.4) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV65168931; called by muse, mutect2, varscan2
- THEG | c.953A>T p.D318V | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV61073606; called by muse, mutect2, varscan2
- TMOD1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52244548; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4001T>A p.L1334Q | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV64100649; called by muse, mutect2, varscan2
- TRIM2 | c.803C>A p.T268N (on ENST00000437508; = p.T295N on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV58632488; called by muse, mutect2
- VPS8 | c.3416G>A p.R1139H (on ENST00000625842 / NM_001349294.1; = p.R1137H on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs758939120, COSV54981795; called by muse, mutect2, varscan2
- ZDBF2 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1188864882, COSV65624077; called by muse, mutect2, varscan2
- ZFX | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58447035, COSV58448850; called by muse, mutect2, varscan2
- ABLIM1 | c.38_39insTTTT p.L13Ffs*6 | Frame Shift Ins (INS) | VAF 51/257 reads (20%) | called by mutect2, pindel, varscan2
- ACOX1 | c.1690_1691del p.L564Vfs*44 | Frame Shift Del (DEL) | VAF 36/321 reads (11%) | called by pindel, varscan2
- CCDC125 | c.373del p.E125Kfs*3 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- CFAP69 | c.273del p.F91Lfs*4 | Frame Shift Del (DEL) | VAF 29/165 reads (18%) | called by mutect2, pindel, varscan2
- CLRN3 | c.571_574del p.N191* | Frame Shift Del (DEL) | VAF 45/275 reads (16%) | called by mutect2, pindel, varscan2
- GIGYF2 | c.3398A>C p.D1133A | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NBAS | c.1815_1821del p.Y605* | Frame Shift Del (DEL) | VAF 51/367 reads (14%) | called by mutect2, pindel, varscan2
- NFU1 | c.265_266insA p.P89Hfs*13 (on ENST00000410022 / NM_001002755.4; = p.P65Hfs*13 on NM_015700.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 21/98 reads (21%) | called by mutect2, pindel*, varscan2
- OSTC | c.34del p.L12Sfs*6 | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | called by mutect2, pindel, varscan2
- POLR2A | c.2543T>C p.I848T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTAF1 | c.3894T>G p.T1298= | Silent (SNP) | VAF 32/196 reads (16%) | catalogued as COSV56432046; called by muse, mutect2, varscan2
- CBR3 | c.723C>A p.I241= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV51741036; called by muse, mutect2, varscan2
- CCDC51 | c.966G>A p.E322= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV56488569; called by muse, mutect2, varscan2
- CD63 | c.126C>T p.T42= | Silent (SNP) | VAF 24/206 reads (12%) | catalogued as COSV57676197; called by muse, mutect2, varscan2
- CYP2A13 | c.34C>T p.L12= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV57837091; called by muse, mutect2, varscan2
- GOLGA1 | c.345C>T p.A115= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as rs1305019443, COSV65229137; called by muse, mutect2, varscan2
- HDX | c.672A>G p.P224= | Silent (SNP) | VAF 90/465 reads (19%) | catalogued as COSV52975191, COSV99946871; called by muse, mutect2, varscan2
- KIDINS220 | c.2470C>A p.R824= | Silent (SNP) | VAF 75/539 reads (14%) | catalogued as COSV56752093; called by muse, mutect2, varscan2
- MYO1H | c.108C>T p.D36= | Silent (SNP) | VAF 64/382 reads (17%) | catalogued as rs759309359, COSV60444505; called by muse, mutect2, varscan2
- OR10A4 | c.72T>G p.L24= | Silent (SNP) | VAF 86/420 reads (20%) | catalogued as COSV65841840; called by muse, mutect2, varscan2
- OR10H2 | c.819C>T p.T273= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as COSV59945763; called by muse, mutect2, varscan2
- PLCG1 | c.2739C>T p.A913= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as rs776818097, COSV54817291; called by muse, mutect2, varscan2
- RINL | c.1347C>G p.P449= (on ENST00000591812 / NM_001195833.2; = p.P335= on NM_198445.4) | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV61574432, COSV61574769; called by muse, mutect2, varscan2
- SLC7A14 | c.2130C>T p.Y710= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as rs201486833; called by muse, mutect2, varscan2
- SRCAP | c.4125C>T p.L1375= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as rs1461747583, COSV52670428, COSV52674928; called by muse, mutect2, varscan2
- TDRKH | c.825T>C p.S275= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV64316172; called by muse, mutect2, varscan2
- TSEN54 | c.1407C>G p.P469= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV51346801; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504245 C>T | 5'Flank (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- RNF217-AS1 | n.1350T>A | RNA (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1838-725G>A | Intron (SNP) | VAF 58/214 reads (27%) | catalogued as COSV52177652; called by muse, mutect2, varscan2
